Surgical pathology report (de-identified scan), TCGA case TCGA-DU-A7TA, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Henry Ford Hospital, specimen TCGA-DU-A7TA-01A (Primary Tumor).

[page 1 of 2]
ICD 6-3

Oligodendroglioma, grade II 9450/3
Site: ^{chf}Brain, supratentorial NOS C71.0
^{path}Brain, occipital lobe C71.4
JA 4/22/14

Anatomic Pathology/Cytology Document State: (version)

Update Date/Time:

Final 1

Patient Name:

MRN:

Service Date/Time:

DOB/Age/Gender:

Male Provider:

Location: Responsible Staff:

Accession #:

Phone Number:

Client:

Location:

Taken:

Received:

Reported:

Physician(s):

Phy Location:

=====

CLINICAL HISTORY

-year-old man with left sided blurred vision and papilledema has a large right occipital, non enhancing brain tumor.

OPERATIVE DIAGNOSES

Not Given

Operation/Specimen: A: Brain, excision biopsy

B: Brain, excision biopsy

PATHOLOGICAL DIAGNOSIS:

A. Brain biopsy: Oligodendroglioma, proliferation index (MIB-1) : 2%

COMMENT

Sections show an oligodendroglioma with a loose, microcystic background. The cellularity is moderate with mild nuclear pleomorphism. There are many minigemistocytes. Mitotic figure is not seen. There is no vascular hyperplasia or necrosis.

Electronically Signed Out

, Senior Staff Pathologist

INTRA-OPERATIVE CONSULTATION

Brain, occipital, biopsy: Glioma (possibly astrocytoma, cannot R/O oligo).

, Senior Staff Pathologist

GROSS DESCRIPTION

A.

Received fresh, three fragments, 0.8 cm. in aggregate. Semi firm, yellowish-grey, glistening. In total, A1 and A2.

B.

SPECIMEN: Brain tumor.

FIXATIVE: None.

GENERAL: Received are two tan-gray rubbery portions of tissue measuring 3.5 x 3 x 1 cm and 3 x 1.5 x 1 cm. SECTIONS: Representative sections in 3 cassettes with reps in the larger portion A1 and A2, smaller portion in B3.

, Senior Staff Pathologist

ICD-9(s):

191.4 191.4

Billing Fee Code(s):

A:

B:

Histo Data

Part A: Brain, excision biopsy

Taken: Received:

Stain/cnt Block Ordered Comment

[page 2 of 2]
H/E x 1 1
MIB1-DA x 1 1
H/E x 1 2
Part B: Brain, excision biopsy
Taken: Received:
Stain/cnt Block Ordered Comment
H/E x 1 1
H/E x 1 2
H/E x 1 3
MIB1-DA x 1 3
*** End of Report ***

Case is (check one): Reviewer Initials: DM	QUALIFIED / DATE Reviewed: 9/10/13	DISQUALIFIED

Source: NCI Genomic Data Commons file 7d9cedde-14ba-4603-9d1e-8b4040fb16ad (TCGA-DU-A7TA.4E9DD63D-7C18-4922-93B5-37B0BB2CCB8F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).